Somatic mutation profile of tumor specimen MP2PRT-PASNVN-TMP1-A (aliquot MP2PRT-PASNVN-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASNVN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,812 days).
Specimen MP2PRT-PASNVN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 064fb1d9-5336-4fc7-9564-cb5cf7bce3d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNVN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNVN-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceb92033-698e-45fd-846e-b8c51582a701

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 62/427 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs747059045, COSV64600275; called by muse, mutect2, varscan2
- ARHGEF28 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs779364770, COSV55252872; called by muse, mutect2, varscan2
- CAMKK1 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752055786; called by muse, mutect2, varscan2
- COL12A1 | c.7652C>T p.S2551L | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59406832; called by muse, mutect2, varscan2
- COL22A1 | c.3056G>T p.G1019V | Missense Mutation (SNP) | VAF 222/545 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as COSV57321085; called by muse, mutect2, varscan2
- GTPBP4 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 135/345 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs144343889; called by muse, mutect2, varscan2
- MAGI2 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 108/501 reads (22%) | catalogued as COSV62656642; called by muse, mutect2, varscan2
- NLN | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV104429113; called by muse, mutect2, varscan2
- OR13C2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV73377777; called by muse, mutect2, varscan2
- SNX7 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as rs150092347; called by muse, mutect2, varscan2
- XAB2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs370819469; called by muse, mutect2, varscan2
- BRINP3 | c.1481A>G p.D494G | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CPNE8 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- CRYBG3 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 81/376 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DCX | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 35/691 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- DNAH7 | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- FOXA3 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 48/588 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by muse, mutect2
- FTCDNL1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.711); called by muse, mutect2
- GPSM2 | c.533_534insCCCC p.Q179Pfs*9 | Frame Shift Ins (INS) | VAF 36/307 reads (12%) | called by mutect2, pindel, varscan2
- GSTCD | c.1388T>G p.L463R (on ENST00000360505 / NM_001031720.3; = p.L376R on NM_024751.3) | Missense Mutation (SNP) | VAF 17/363 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2
- RCAN3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 76/430 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, varscan2
- TLN2 | c.4907C>A p.A1636D | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.47414G>C p.R15805T (on ENST00000591111; = p.R8381T on NM_003319.4) | Missense Mutation (SNP) | VAF 74/395 reads (19%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163 | c.1545A>G p.L515= | Silent (SNP) | VAF 54/267 reads (20%) | catalogued as rs200789023; called by muse, mutect2, varscan2
- CHPT1 | c.63G>C p.L21= | Silent (SNP) | VAF 66/591 reads (11%) | catalogued as rs749250020; called by muse, mutect2, varscan2
- GRK1 | c.1611C>T p.D537= | Silent (SNP) | VAF 26/353 reads (7%) | catalogued as rs372693970; called by muse, mutect2
- PKD2L2 | c.144G>A p.G48= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as rs1454485169; called by muse, mutect2
- TLN2 | c.5568G>A p.T1856= | Silent (SNP) | VAF 89/428 reads (21%) | catalogued as rs528484217; called by muse, mutect2, varscan2
- ZNF507 | c.771T>C p.C257= | Silent (SNP) | VAF 48/407 reads (12%) | called by muse, mutect2, varscan2
